Somatic mutation profile of tumor specimen TCGA-E8-A44M-01A (aliquot TCGA-E8-A44M-01A-21D-A23U-08) from TCGA case TCGA-E8-A44M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 23.3 years (8,523 days).
Specimen TCGA-E8-A44M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 746b89af-9c90-4e1f-b51c-98279147545a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A44M-10A (Blood Derived Normal), aliquot TCGA-E8-A44M-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a254fef6-2844-4be3-8ff1-e279d259b3bd

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GIMAP6 | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 58/314 reads (18%) | catalogued as COSV61035018; called by muse, mutect2, varscan2
- PCYOX1L | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV51005835; called by muse, mutect2, varscan2
- MOV10 | c.2812_2848del p.C938Lfs*16 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel
